Somatic mutation profile of tumor specimen TCGA-IG-A3YB-01A (aliquot TCGA-IG-A3YB-01A-11D-A247-09) from TCGA case TCGA-IG-A3YB, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.1 years (22,316 days).
Specimen TCGA-IG-A3YB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b31a8be-1fa3-419a-ac7c-9e26ede8944d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A3YB-10A (Blood Derived Normal), aliquot TCGA-IG-A3YB-10A-01D-A247-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58597c73-a70e-440a-a671-5db4c0dda167

The open-access MAF lists 84 somatic variants for this specimen: 66 protein-altering or splice-affecting, 14 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 14, Nonsense Mutation 6, Frame Shift Del 5, Splice Site 4, Intron 2, Frame Shift Ins 2, RNA 2, In Frame Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GRXCR1 | c.784C>T p.R262* | Nonsense Mutation (SNP) | VAF 18/161 reads (11%) | catalogued as rs761349153, CM153971, COSV67670021; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.3736del p.L1246Ffs*29 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as CM129565, COSV64673750; called by mutect2, varscan2
- AP1G2 | c.460G>A p.V154M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs748909761, COSV58110660; called by muse, mutect2, varscan2
- APBB1 | c.1352G>A p.R451H | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772042074; called by muse, mutect2, varscan2
- C14orf39 | c.617C>A p.S206* | Nonsense Mutation (SNP) | VAF 5/79 reads (6%) | catalogued as COSV58779299; called by muse, mutect2
- CFAP92 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757373715, COSV54045787; called by muse, mutect2, varscan2
- CLEC3A | c.147G>T p.K49N (on ENST00000651443; = p.K40N on NM_005752.6) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs757280362; called by muse, mutect2, varscan2
- CSMD3 | c.9551G>C p.R3184T (on ENST00000297405 / NM_001363185.1; = p.R3015T on NM_052900.3) | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV52320355; called by muse, mutect2, varscan2
- DOCK6 | c.1286G>A p.R429H | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.701); catalogued as rs748891692; called by muse, mutect2, varscan2
- DSN1 | c.426C>A p.F142L | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as COSV65519499; called by muse, mutect2, varscan2
- FAM171B | c.814C>G p.Q272E | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV59010167; called by muse, mutect2, varscan2
- GNPTG | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99136132; called by muse, varscan2
- GPR84 | c.83T>G p.V28G | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs868793018, COSV57210290; called by muse, mutect2, varscan2
- IGF2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 28/55 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100323835; called by muse, mutect2, varscan2
- LDHAL6B | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as rs756211974; called by muse, mutect2, varscan2
- LRP5 | c.1833del p.C612Afs*23 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | catalogued as CM053295, CM053961; called by mutect2, pindel, varscan2
- MPIG6B | c.667C>T p.R223C (on ENST00000649779 / NM_138272.3; = p.P229L on NM_025260.4) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs748914079, COSV65389869; called by muse, mutect2, varscan2
- MRC1 | c.1919C>T p.T640M | Missense Mutation (SNP) | VAF 80/236 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs970799233; called by muse, mutect2, varscan2
- MS4A8 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as COSV55754240; called by muse, mutect2, varscan2
- NDRG2 | c.740G>A p.R247H (on ENST00000298687 / NM_001354570.1; = p.R233H on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747046310; called by muse, mutect2, varscan2
- NEB | c.4561G>A p.E1521K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.442); catalogued as COSV99424550; called by muse, mutect2, varscan2
- OR52K1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs768055536, COSV56903202; called by muse, mutect2, varscan2
- PCDHA10 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 93/148 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56532873; called by muse, mutect2, varscan2
- PIGS | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | catalogued as rs762251130; called by muse, mutect2, varscan2
- PPFIA2 | c.1838C>G p.P613R | Missense Mutation (SNP) | VAF 53/86 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as rs1440286058, COSV61046764; called by muse, mutect2, varscan2
- PSG4 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 105/243 reads (43%) | SIFT tolerated (0.63); PolyPhen benign (0.047); catalogued as rs576741968, COSV54934459, COSV54939080; called by muse, mutect2, varscan2
- SLC6A3 | c.1639C>A p.H547N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs781299950, COSV54369548; called by muse, mutect2, varscan2
- SPTAN1 | c.4280del p.R1427Lfs*13 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | catalogued as COSV100824046; called by mutect2, pindel, varscan2
- TP53 | c.383del p.P128Lfs*42 | Frame Shift Del (DEL) | VAF 19/44 reads (43%) | catalogued as COSV53283607; called by mutect2, pindel, varscan2
- ANKRD30A | c.3268-2A>T p.X1090_splice (on ENST00000611781; = p.X1034_splice on NM_052997.2) | Splice Site (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- ARHGEF12 | c.1387C>T p.H463Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.317); called by muse, mutect2
- ASNS | c.1525A>G p.T509A | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- ASTN2 | c.3806G>T p.R1269L (on ENST00000313400 / NM_001365069.1; = p.R1218L on NM_014010.5) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- B3GNT8 | c.928T>C p.Y310H | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BOD1L1 | c.8252G>T p.G2751V | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CCNL2 | c.654_659+2del p.X218_splice | Splice Site (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- EXOC8 | c.1106A>G p.D369G | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- FAM184A | c.2965G>C p.D989H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCGBP | c.5611C>T p.Q1871* | Nonsense Mutation (SNP) | VAF 20/188 reads (11%) | called by muse, mutect2
- FCGBP | c.5610G>T p.E1870D | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- FKBP4 | c.673T>C p.Y225H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- H3C7 | c.306_312dup p.F105Gfs*4 | Frame Shift Ins (INS) | VAF 26/128 reads (20%) | called by mutect2, varscan2
- HECW2 | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- KIF5C | c.1682T>A p.I561K | Missense Mutation (SNP) | VAF 176/218 reads (81%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- LCN6 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 65/90 reads (72%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAP2 | c.2294A>T p.E765V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- MDN1 | c.12608A>C p.H4203P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- MROH1 | c.2404_2405dup p.I803Pfs*23 | Frame Shift Ins (INS) | VAF 37/118 reads (31%) | called by mutect2, pindel, varscan2
- PCDH7 | c.1958_1960dup p.Q653dup | In Frame Ins (INS) | VAF 18/45 reads (40%) | called by mutect2, pindel, varscan2
- PHF8 | c.2757+2T>G p.X919_splice (on ENST00000357988 / NM_001184896.1; = p.X883_splice on NM_015107.3) | Splice Site (SNP) | VAF 37/54 reads (69%) | called by muse, mutect2, varscan2
- PLA2G12A | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- POLH | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PRKD2 | c.1213G>T p.V405F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RGS6 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SIGLEC9 | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SLC13A4 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- SLFNL1 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ST18 | c.49A>T p.T17S | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAF1L | c.5129G>A p.R1710K | Missense Mutation (SNP) | VAF 101/156 reads (65%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TLR10 | c.490C>G p.H164D | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2
- TNR | c.3794-1G>T p.X1265_splice | Splice Site (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- TTC21B | c.2791C>T p.Q931* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | called by muse, mutect2, varscan2
- UBXN4 | c.1246G>C p.G416R | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZNF318 | c.5889G>C p.K1963N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF667 | c.159del p.G54Vfs*9 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- ADAMTS2 | c.3432C>G p.L1144= | Silent (SNP) | VAF 20/87 reads (23%) | called by muse, mutect2, varscan2
- ATP13A2 | c.1755G>A p.L585= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs200184146; called by muse, mutect2, varscan2
- KCNH4 | c.1416G>C p.G472= | Silent (SNP) | VAF 51/77 reads (66%) | catalogued as COSV52915177; called by muse, mutect2, varscan2
- MAP1B | c.6453C>T p.S2151= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs543732551; called by muse, mutect2, varscan2
- MSLNL | c.1839C>T p.H613= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- MYO18B | c.903C>T p.D301= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs369200662; called by muse, mutect2, varscan2
- NWD1 | c.1543C>T p.L515= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs757776142; called by muse, mutect2, varscan2
- PCNX2 | c.1410C>T p.Y470= | Silent (SNP) | VAF 25/47 reads (53%) | catalogued as rs771369510, COSV99266738; called by muse, mutect2, varscan2
- PDPR | c.2565C>G p.L855= | Silent (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- RASA3 | c.486G>T p.G162= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV61868365; called by muse, mutect2, varscan2
- RP1 | c.2622G>T p.G874= | Silent (SNP) | VAF 10/72 reads (14%) | called by muse, mutect2, varscan2
- SEC23A | c.1368C>T p.T456= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- TEC | c.1543C>T p.L515= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs1560369737; called by muse, mutect2
- ZMYM6 | c.525G>A p.E175= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1299780554; called by muse, mutect2, varscan2
- C8orf86 | n.484G>C | RNA (SNP) | VAF 30/56 reads (54%) | catalogued as rs749051081; called by muse, mutect2
- EIF5A | c.-22+778A>T | Intron (SNP) | VAF 25/105 reads (24%) | called by muse, mutect2, varscan2
- MBNL1 | c.1111-1080A>G | Intron (SNP) | VAF 33/78 reads (42%) | called by muse, mutect2, varscan2
- MIRLET7F1 | n.16A>T | RNA (SNP) | VAF 39/53 reads (74%) | called by muse, mutect2, varscan2
